Somatic mutation profile of tumor specimen TCGA-IK-7675-01A (aliquot TCGA-IK-7675-01A-11D-2086-08) from TCGA case TCGA-IK-7675, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 43.5 years (15,900 days).
Specimen TCGA-IK-7675-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7c7cfec-4447-4d3f-9ccf-3fcb26f6db7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IK-7675-10A (Blood Derived Normal), aliquot TCGA-IK-7675-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5bdbdbb-d254-447a-927d-3e65121b0e00

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 31, Silent 9, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 66/128 reads (52%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 23/28 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs566735897, COSV60918359; called by muse, mutect2, varscan2
- ADAM28 | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV56105604; called by muse, mutect2, varscan2
- AFP | c.1346C>T p.A449V | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs1242357916, COSV56927196; called by muse, mutect2, varscan2
- CASC3 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV52869384, COSV99230069; called by muse, mutect2, varscan2
- CNTNAP3 | c.1820T>G p.I607S | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV52665381, COSV52675775; called by muse, mutect2, varscan2
- FANCB | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 84/98 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60761825; called by muse, mutect2, varscan2
- FGFRL1 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.582); catalogued as rs1392108005, COSV53257428, COSV53259785; called by muse, mutect2, varscan2
- G6PC | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.829); catalogued as COSV53832728; called by muse, mutect2, varscan2
- GALNT17 | c.1332G>C p.K444N | Missense Mutation (SNP) | VAF 71/193 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV61192470; called by muse, mutect2, varscan2
- GGA2 | c.1121C>A p.A374E | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.476); catalogued as COSV59170563; called by muse, mutect2, varscan2
- GRPR | c.841C>A p.H281N | Missense Mutation (SNP) | VAF 171/194 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66669319, COSV66670311; called by muse, mutect2, varscan2
- IRS1 | c.2306G>A p.R769K | Missense Mutation (SNP) | VAF 173/381 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV59340073; called by muse, mutect2, varscan2
- JPH2 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs750791531, COSV65902250; called by muse, mutect2, varscan2
- KRTAP20-2 | c.65A>G p.Y22C | Missense Mutation (SNP) | VAF 74/149 reads (50%) | PolyPhen benign (0.012); catalogued as rs761692576, COSV58183799; called by muse, mutect2, varscan2
- MROH2B | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as COSV68181253, COSV68189614; called by muse, mutect2, varscan2
- NOTCH2 | c.4120T>A p.C1374S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV56706378; called by muse, mutect2, varscan2
- OR1N2 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV65461221; called by muse, mutect2, varscan2
- OR2L2 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63561114; called by muse, mutect2, varscan2
- PCNX3 | c.5447G>A p.R1816H | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as rs752910708, COSV63139287, COSV63140904; called by muse, mutect2, varscan2
- PKHD1 | c.3610T>C p.C1204R | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs999887393, COSV61895253; called by muse, mutect2, varscan2
- PYGL | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs767847163; called by mutect2, varscan2
- RASIP1 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.321); catalogued as rs777092955, COSV55808484, COSV99711158; called by muse, mutect2, varscan2
- RFX1 | c.1922A>G p.Y641C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs930407483, COSV54333650; called by muse, mutect2, varscan2
- SFT2D2 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 137/321 reads (43%) | catalogued as COSV54800894; called by muse, mutect2, varscan2
- SPATA17 | c.434A>G p.E145G | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV65126264; called by muse, mutect2, varscan2
- STPG2 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212234699, COSV54821501; called by muse, mutect2, varscan2
- TPR | c.6286C>T p.P2096S | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV66605125; called by muse, mutect2, varscan2
- TRIM58 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV63571419, COSV63572326; called by muse, mutect2, varscan2
- VWA8 | c.3112A>G p.K1038E | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV55705566; called by muse, mutect2, varscan2
- ZNF609 | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV58590291; called by muse, mutect2, varscan2
- AMBRA1 | c.2782_2791dup p.L931Pfs*3 (on ENST00000458649 / NM_001367468.1; = p.L841Pfs*3 on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (INS) | VAF 26/35 reads (74%) | called by mutect2, varscan2
- OR5H15 | c.227C>A p.T76K | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2
- COL5A2 | c.1206G>A p.G402= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs763376408, COSV66415386; called by muse, mutect2, varscan2
- HLA-DOA | c.663T>C p.C221= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV57715599; called by muse, mutect2, varscan2
- OR2T35 | c.717T>A p.A239= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2, varscan2
- OR9G1 | c.375C>T p.I125= | Silent (SNP) | VAF 8/228 reads (4%) | catalogued as COSV56450447, COSV56454312; called by muse, mutect2
- PLEKHA5 | c.2085T>C p.D695= | Silent (SNP) | VAF 63/130 reads (48%) | catalogued as COSV54712651; called by muse, mutect2, varscan2
- RABEP1 | c.1008A>G p.K336= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV52588546; called by muse, mutect2, varscan2
- SCN10A | c.2925A>G p.Q975= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV71862694; called by muse, mutect2, varscan2
- WDR81 | c.4995C>T p.S1665= (on ENST00000409644 / NM_001163809.2; = p.S614= on NM_152348.4) | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as rs143987787; called by muse, mutect2, varscan2
- ZZEF1 | c.327C>T p.A109= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs539179364; called by muse, mutect2
